Surgical pathology report (de-identified scan), TCGA case TCGA-86-7954, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Asterand, specimen TCGA-86-7954-01A (Primary Tumor).

[page 1 of 5]
Case ID	ID	Gross Description
		Labeled right lower lobe (bronchial margin). Received fresh for intraoperative consultation is a 162 g lower lobe of lung measuring 14.5 x 11.5 x 3.5 cm. The pleural surface is tan to gray-brown and lightly wrinkled with 3 subpleural nodular structures ranging from 0.4 to 0.6 cm along the base. Along the posterolateral aspect near the base is a 2.7 x 1.0 cm firm tan subpleural mass that comes to within approximately 5 cm of the bronchial margin, which is shaved and submitted for frozen section. The overlying pleura is puckering and is focally inked blue. Sectioning through the separate subpleural nodules reveals glistening gray-tan cut surfaces. The background lung is tan to red and spongy white to white-tan hilar lymph node measuring 0.5 and 0.6 cm.

[page 2 of 5]
Microscopic Description

The bronchial margin is negative for carcinoma. In the section from the bronchial margin, a small lymph node is identified which is negative for metastatic carcinoma. Also, there are two additional hilar lymph nodes which are both negative for metastatic carcinoma. The lung mass is an invasive poorly differentiated adenocarcinoma merging with a peripheral bronchioloalveolar type pattern. The invasive carcinoma focally involves the visceral pleura surface. In this area, free floating tumor cells are seen in blood clot external to the visceral pleura surface. The vascular margins are negative for neoplasm. No angiolymphatic space involvement by tumor is seen. The separate subpleural nodules are consistent with small foci of metaplastic epithelial proliferations (honeycombing). These nodules are composed of epithelial cells that have a mucinous as well as nonmucinous appearance and many demonstrate cilia. There is a focus of squamous metaplasia associated with one of these areas. There is no nuclear atypia. Nonneoplastic lung shows emphysematous features. Immunohistochemical stains are performed for CK7, CK20, TTF-1, CDX 2 and Napsin A. Control material for each individual stain demonstrates appropriate staining. The malignant cells are positive for Napsin A, CK7 and TTF-1. There is focal positivity for CK20. The malignant cells are negative for CDX 2. These findings support the interpretation of a primary lung adenocarcinoma.

[page 3 of 5]
Diagnosis Details	Comments
LUNG CARCINOMA CHECKLIST 1. Tumor Type: Adenocarcinoma.2. Tumor grade: Poorly differentiated.3. Tumor location: Right lower lobe.4. Tumor size: 2.7 x 1.0 cm.5. Angiolymphatic invasion: No.6. Bronchial margin: Free of tumor.7. Pleural involvement: Present, there is involvement of the visceral pleural by invasive carcinoma.8. Lymph nodes: 16 lymph nodes are negative for metastatic carcinoma (0/16).9. Size of largest metastatic deposit: N/A.10. TNM: pT2 (PL2),N0,MX.	

[page 4 of 5]
Formatted Path Report

LUNG TISSUE CHECKLIST

Specimen type: Lobectomy

Tumor site: Lung

Tumor size: 2.7 x 1 cm

Histologic type: Bronchiolo-alveolar adenocarcinoma

Histologic grade: Poorly differentiated

Tumor extent: Visceral pleura

Other tumor nodules: Not specified

Lymph nodes: 0/16 positive for metastasis (Right lower lobe artery, bronchial margin, subcari 0/16)

Lymphatic invasion: Absent

Venous invasion: Absent

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

Laterality

Right-lower

[page 5 of 5]
Excision date

--	--	--

--

Source: NCI Genomic Data Commons file f62c44d7-15e6-4125-bc8a-132bf95343bd (TCGA-86-7954.6A0C9A64-8C57-412A-8B3C-EFB8E0B184EA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).